Gene-level copy-number profile of tumor specimen TCGA-14-4157-01A from TCGA case TCGA-14-4157, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 40.6 years (14,816 days).
Specimen TCGA-14-4157-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.b3a4c3ef-9959-4bc5-ba4b-9272b1c9d40c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-14-4157-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/69ab8b44-63b5-4e68-bbaf-aa43b9b883bc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 75; copy number 1: 9,039; copy number 2: 46,164; copy number 3: 4,542.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-14-4157-01A-01D-1224-01): tumor purity 0.98, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–1): FOCAD.
- chr9:20,786,927–24,088,051, 72 genes (broad region; genes not listed).
- chr9:28,863,626–28,888,955, 2 genes: MIR876, MIR873.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,652. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
